MMRF case MMRF_1824 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b53d32bf-44fb-4135-9c10-037fe46ca1e9

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.0 years (25,202 days); ISS stage: II; Days to last known disease status: 982 days (2.7 years); Days to last follow up: 982 days (2.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 163 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 220 days; Days to treatment end: 220 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 221 days; Days to treatment end: 221 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 325 days; Days to treatment end: 430 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 430 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 501 mg/dL; Immunoglobulin G 29.5 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.79 g/L; Beta 2 Microglobulin 4.2 µg/mL; Hemoglobin 6.2 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 9.2 g/dL; Glucose 5.23 mmol/L.
- Day 57 (ECOG 1): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 186 mg/dL; Immunoglobulin G 17.9 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 5.12 mmol/L.
- Day 148 (ECOG 1): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 31.7 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 4.28 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 248 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.22 mg/dL; Immunoglobulin G 8.85 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.1 µg/mL; Hemoglobin 6.51 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.89 mmol/L.
- Day 325 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.65 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 430 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.27 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 4.95 mmol/L.
- Day 521 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.2 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 4.73 mmol/L.
- Day 624 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.5 mg/dL; Immunoglobulin G 19.3 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Glucose 5.12 mmol/L.
- Day 687 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.7 mg/dL; Immunoglobulin G 22 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 7.7 g/dL; Glucose 4.46 mmol/L.
- Day 771 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.6 mg/dL; Immunoglobulin G 25.2 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 8.5 g/dL; Glucose 5.28 mmol/L.
- Day 891 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 31.2 mg/dL; Immunoglobulin G 19.9 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 4.68 mmol/L.
- Day 982 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 36.2 mg/dL; Immunoglobulin G 19.7 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.85 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day -20: Weight: 92 kg; Height: 173 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample MMRF_1824_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_1824_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
